Somatic mutation profile of tumor specimen TCGA-WB-A80M-01A (aliquot TCGA-WB-A80M-01A-11D-A35I-08) from TCGA case TCGA-WB-A80M, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 63.4 years (23,163 days).
Specimen TCGA-WB-A80M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd69062e-8a91-4afa-a977-e7b94d9a474d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A80M-10A (Blood Derived Normal), aliquot TCGA-WB-A80M-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63b0fdc6-55fb-4d61-851f-b8d2f2d8e4f8

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Splice Site 1, Silent 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IFIT3 | c.904G>A p.G302R | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.521); catalogued as rs760182387; called by muse, mutect2, varscan2
- OR1J1 | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs373376555; called by muse, mutect2, varscan2
- PLCL1 | c.2158C>T p.P720S | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs752227939; called by muse, mutect2, varscan2
- CSDE1 | c.1641-2A>T p.X547_splice (on ENST00000358528 / NM_001007553.3; = p.X516_splice on NM_007158.6) | Splice Site (SNP) | VAF 54/73 reads (74%) | called by muse, mutect2, varscan2
- CXXC5 | c.185G>A p.S62N | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); called by muse, mutect2
- GTF2A1 | c.1055_1066del p.H352_G356delinsR | In Frame Del (DEL) | VAF 24/127 reads (19%) | called by mutect2, pindel, varscan2
- OMD | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- WDFY3 | c.7887G>T p.V2629= | Silent (SNP) | VAF 27/55 reads (49%) | called by muse, mutect2, varscan2
- CALCR | c.51+2942C>T | Intron (SNP) | VAF 33/80 reads (41%) | called by muse, mutect2, varscan2
